Somatic mutation profile of tumor specimen TCGA-61-1899-01A (aliquot TCGA-61-1899-01A-01W-0639-09) from TCGA case TCGA-61-1899, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 81.3 years (29,692 days).
Specimen TCGA-61-1899-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fed6040-5de5-4a1a-aaf6-53430461840e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1899-11A (Solid Tissue Normal), aliquot TCGA-61-1899-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6df62ca8-920d-4481-b59a-1221b5d2f637

The open-access MAF lists 70 somatic variants for this specimen: 49 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 17, Frame Shift Ins 3, RNA 3, Splice Region 2, Nonsense Mutation 2, Splice Site 2, In Frame Del 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 130/146 reads (89%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A2M | c.1475A>G p.K492R | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV100589057; called by muse, mutect2
- A2ML1 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100229254, COSV100229543; called by muse, mutect2
- ABCA1 | c.5690G>A p.R1897Q | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs564049659, COSV101037444, COSV66070736; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC008676.3 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV56638170; called by muse, mutect2, varscan2
- ATP13A3 | c.2354C>G p.A785G | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99757688; called by muse, mutect2
- BRWD1 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1205091198, COSV58123756; called by muse, mutect2, varscan2
- CCDC141 | c.3776G>T p.G1259V | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); catalogued as rs551700764, COSV55382888; called by muse, mutect2, varscan2
- CCR3 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as rs199944063, COSV62462789, COSV62465113; called by muse, mutect2, varscan2
- CSMD3 | c.9690T>A p.A3230= (on ENST00000297405 / NM_001363185.1; = p.A3061= on NM_052900.3) | Splice Region (SNP) | VAF 46/259 reads (18%) | catalogued as COSV52326776; called by muse, mutect2, varscan2
- CYTL1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV57038311; called by muse, mutect2, varscan2
- DOCK6 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs557547319, COSV52949666; called by muse, mutect2, varscan2
- EHD3 | c.1012A>G p.I338V | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.05); catalogued as COSV59033156; called by muse, mutect2, varscan2
- F2R | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as rs777334197, COSV59930250; called by muse, mutect2, varscan2
- HAUS4 | c.651G>C p.K217N | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as COSV99247161; called by muse, mutect2
- IFNLR1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 136/200 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs772933526, COSV59527674; called by muse, mutect2, varscan2
- ITPR1 | c.6906A>G p.G2302= (on ENST00000354582; = p.G2247= on NM_002222.7) | Splice Region (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100233348; called by muse, mutect2
- KCNAB1 | c.479G>A p.W160* (on ENST00000490337 / NM_172160.3; = p.W149* on NM_003471.3) | Nonsense Mutation (SNP) | VAF 21/175 reads (12%) | catalogued as COSV56754627; called by muse, mutect2, varscan2
- KIFC1 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV65729871; called by muse, mutect2
- LILRB4 | c.1000G>A p.V334M (on ENST00000391733 / NM_001278428.3; = p.V333M on NM_001278426.3) | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs532643436, COSV54408803; called by muse, mutect2, varscan2
- MARCHF4 | c.1135T>C p.Y379H | Missense Mutation (SNP) | VAF 59/78 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56108827; called by muse, mutect2, varscan2
- MYF5 | c.396G>C p.E132D | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57356686; called by muse, mutect2, varscan2
- MYO5B | c.1404+1G>C p.X468_splice | Splice Site (SNP) | VAF 47/311 reads (15%) | catalogued as COSV53231714; called by muse, mutect2, varscan2
- OR4N2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 129/573 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs770622276, COSV60050519; called by muse, mutect2, varscan2
- OR5M3 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV56568606; called by muse, mutect2, varscan2
- PCDHB8 | c.1100C>A p.A367E | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV50794655, COSV99177469; called by muse, mutect2, varscan2
- PHF20 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 172/375 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV59189064; called by muse, mutect2, varscan2
- PIK3CB | c.2626T>C p.F876L | Missense Mutation (SNP) | VAF 110/169 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56690526; called by muse, mutect2, varscan2
- PRDM5 | c.256C>A p.H86N | Missense Mutation (SNP) | VAF 22/541 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53363760; called by muse, mutect2
- PRRC2C | c.1976C>T p.P659L (on ENST00000367742; = p.P657L on NM_015172.4) | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs767304369, COSV58913807; called by muse, mutect2, varscan2
- RGS1 | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs967359970, COSV66506572; called by muse, mutect2, varscan2
- RIPK2 | c.1072C>G p.P358A | Missense Mutation (SNP) | VAF 74/340 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1339588448, COSV55135176; called by muse, mutect2, varscan2
- RNF115 | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 92/162 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV65166034; called by muse, mutect2, varscan2
- SEMA3C | c.1913A>T p.Q638L | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as COSV54851249, COSV54856244; called by muse, mutect2, varscan2
- SETDB2 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99321043; called by muse, mutect2, varscan2
- SETDB2 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99321044; called by muse, mutect2, varscan2
- SPICE1 | c.1585A>G p.I529V | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs758747360, COSV55625320; called by muse, mutect2, varscan2
- SYCP2L | c.745C>A p.L249I | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV51650098; called by muse, mutect2, varscan2
- TMPRSS15 | c.2071G>T p.V691L | Missense Mutation (SNP) | VAF 60/736 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.454); catalogued as COSV99519421; called by muse, mutect2
- USP7 | c.458G>C p.R153P | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV61217640; called by muse, mutect2, varscan2
- VAC14 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.082); catalogued as COSV55758053; called by muse, mutect2, varscan2
- ZNF28 | c.915C>A p.D305E | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1346312315, COSV100354195; called by muse, mutect2
- ZNF341 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs765975428, COSV61010909; called by muse, mutect2, varscan2
- ZNF778 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV60602871; called by muse, mutect2, varscan2
- LDB1 | c.404dup p.A136Cfs*9 (on ENST00000425280 / NM_001321612.2; = p.A100Cfs*9 on NM_003893.5) | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by pindel, varscan2
- LYAR | c.979del p.I327* | Frame Shift Del (DEL) | VAF 63/174 reads (36%) | called by mutect2, pindel, varscan2
- RALY | c.154dup p.S52Ffs*14 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- RPAP2 | c.1799_1804del p.S600_L601del | In Frame Del (DEL) | VAF 100/513 reads (19%) | called by pindel*, varscan2
- SH3PXD2B | c.2441dup p.Q815Pfs*3 | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | called by pindel, varscan2
- AGO1 | c.2214C>A p.I738= | Silent (SNP) | VAF 14/330 reads (4%) | catalogued as COSV100940933; called by muse, mutect2
- AKAP8L | c.264C>T p.A88= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs762901365, COSV101275888; called by muse, mutect2
- ARMH4 | c.60C>T p.S20= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as rs769028630, COSV50774753; called by muse, mutect2, varscan2
- ATP1B4 | c.18G>T p.R6= | Silent (SNP) | VAF 19/326 reads (6%) | catalogued as COSV99486593; called by muse, mutect2
- EIF3G | c.393C>T p.I131= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99462980; called by muse, mutect2
- GPR37 | c.1755C>T p.N585= | Silent (SNP) | VAF 36/183 reads (20%) | catalogued as COSV58255947; called by muse, mutect2, varscan2
- LRP1B | c.3531G>C p.S1177= | Silent (SNP) | VAF 23/210 reads (11%) | catalogued as COSV67226444; called by muse, mutect2, varscan2
- NCAM2 | c.237C>T p.T79= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV53104939; called by muse, mutect2, varscan2
- NPHS2 | c.519G>A p.E173= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV62636683; called by muse, mutect2, varscan2
- OR2M4 | c.43C>T p.L15= | Silent (SNP) | VAF 52/257 reads (20%) | catalogued as COSV60709784; called by muse, mutect2, varscan2
- OR5B2 | c.585G>T p.V195= | Silent (SNP) | VAF 122/366 reads (33%) | catalogued as COSV100222832, COSV100222996; called by muse, mutect2
- PTPRN2 | c.1401C>T p.A467= | Silent (SNP) | VAF 44/62 reads (71%) | catalogued as rs772404937, COSV67046949; called by muse, mutect2, varscan2
- SLC17A3 | c.939C>T p.S313= | Silent (SNP) | VAF 40/420 reads (10%) | catalogued as rs1391355283, COSV57761503; called by muse, mutect2
- TASOR2 | c.6351A>G p.E2117= | Silent (SNP) | VAF 62/187 reads (33%) | catalogued as COSV60169757; called by muse, mutect2, varscan2
- TERB2 | c.477G>A p.Q159= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as rs1306710992, COSV100546640; called by muse, mutect2, varscan2
- TTN | c.54594T>C p.G18198= (on ENST00000591111; = p.G10774= on NM_003319.4) | Silent (SNP) | VAF 22/469 reads (5%) | catalogued as COSV100632204; called by muse, mutect2
- ZNF423 | c.268C>T p.L90= (on ENST00000563137 / NM_001379286.1; = p.L82= on NM_015069.4) | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV52205369; called by muse, mutect2, varscan2
- MIR519E | n.25G>A | RNA (SNP) | VAF 82/202 reads (41%) | catalogued as rs1199021002; called by muse, varscan2
- MIR519E | n.26G>A | RNA (SNP) | VAF 80/201 reads (40%) | catalogued as rs1249808405; called by muse, varscan2
- MIR544A | n.31G>T | RNA (SNP) | VAF 7/45 reads (16%) | catalogued as rs542524627; called by muse, mutect2
- ST6GALNAC2 | chr17:76561127 C>T | 3'Flank (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
